CPTAC case C3N-02153 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3cbd921-6680-46d3-8de5-db5bcb94228d

Demographics
Sex at birth: male; Race: asian; Year of birth: 1962; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 55.4 years (20,241 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 402 days (1.1 years); Progression or recurrence: no; Days to last follow up: 402 days (1.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 2 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 2; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 402 days (1.1 years); Disease response: Complete Response; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 402 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 62 kg; Height: 167 cm; BMI: 22.23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02153-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 270 mg.
- Sample C3N-02153-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 260 mg; Time between clamping and freezing: 23 minutes; Time between excision and freezing: 6 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02153-22: Section location: Lung; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3N-02153-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-02153-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 260 mg.
- Sample C3N-02153-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 260 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 5 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02153-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Samples C3N-02153-31, C3N-02153-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02153-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw.
